Somatic mutation profile of tumor specimen TARGET-10-PATHFE-09A (aliquot TARGET-10-PATHFE-09A-01D) from TARGET case TARGET-10-PATHFE, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,081 days).
Specimen TARGET-10-PATHFE-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7da7a9f8-1fac-490d-83b3-30e12ac57f49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATHFE-10A (Blood Derived Normal), aliquot TARGET-10-PATHFE-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c0f45ec-14d7-4d11-98e2-5b8119ea003a

The open-access MAF lists 33 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Frame Shift Ins 4, Intron 3, Frame Shift Del 2, Nonsense Mutation 1, Nonstop Mutation 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1436G>A p.R479Q (on ENST00000281708 / NM_001349798.2; = p.R399Q on NM_018315.5) | Missense Mutation (SNP) | VAF 47/112 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs866987936, COSV55890822, COSV55894913, COSV55899054; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0A1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52873790; called by muse, mutect2, varscan2
- BNC1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs781164986, COSV61757015; called by muse, mutect2
- CDKN1B | c.596A>C p.*199Sext*60 | Nonstop Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV57430013, COSV57431103; called by muse, mutect2, varscan2
- FOXI3 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 44/91 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1427389100, COSV67916788; called by muse, mutect2, varscan2
- KRTAP9-3 | c.397G>C p.A133P | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs1327496617, COSV101370191, COSV68616521; called by muse, mutect2, varscan2
- NOTCH1 | c.4799T>C p.L1600P | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53025622, COSV53031185; called by muse, varscan2
- NOTCH1 | c.4793G>C p.R1598P | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as COSV53027279, COSV53097635; called by muse, varscan2
- PCNX3 | c.454C>T p.R152* | Nonsense Mutation (SNP) | VAF 63/131 reads (48%) | catalogued as COSV58419859; called by muse, mutect2, varscan2
- RGS7 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.8); catalogued as rs745956675, COSV58543396; called by muse, mutect2, varscan2
- RPL10 | c.292C>A p.R98S | Missense Mutation (SNP) | VAF 9/9 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as COSV50009981, COSV50010241; called by muse, mutect2, varscan2
- RUNX1T1 | c.1429G>A p.D477N (on ENST00000265814 / NM_001198628.1; = p.D450N on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.21); catalogued as rs569622614, COSV56148600; called by muse, mutect2, varscan2
- SP140 | c.192del p.M65Wfs*27 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | catalogued as COSV59447957; called by mutect2, pindel, varscan2
- ZBTB33 | c.506_507del p.E169Vfs*10 | Frame Shift Del (DEL) | VAF 6/43 reads (14%) | catalogued as rs782636794; called by pindel, varscan2
- BCL11B | c.2533A>G p.T845A (on ENST00000357195 / NM_001282237.2; = p.T774A on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DYNC1H1 | c.9401_9402insTAGGCCC p.Q3135Rfs*89 | Frame Shift Ins (INS) | VAF 18/39 reads (46%) | called by mutect2, pindel, varscan2
- FCSK | c.2892_2893insAGGAGTG p.Q966Sfs*5 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | called by mutect2, pindel*, varscan2
- PCSK5 | c.3634G>A p.V1212I | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- PTTG1 | c.450dup p.E151Rfs*6 | Frame Shift Ins (INS) | VAF 38/86 reads (44%) | called by mutect2, varscan2
- PTTG1 | c.451delinsCC p.E151Pfs*6 | Frame Shift Ins (INS) | VAF 40/123 reads (33%) | called by mutect2*, pindel, varscan2*
- TRIM49B | c.178G>A p.G60R | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCAM | c.393G>A p.A131= | Silent (SNP) | VAF 50/95 reads (53%) | catalogued as rs776844243; called by muse, mutect2, varscan2
- DNAI3 | c.2121G>A p.P707= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1258613470, COSV54001709; called by muse, mutect2, varscan2
- DPH1 | c.312C>T p.D104= | Silent (SNP) | VAF 41/84 reads (49%) | catalogued as rs748100653, COSV53985237; called by muse, mutect2, varscan2
- HEXB | c.240C>T p.S80= | Silent (SNP) | VAF 10/119 reads (8%) | called by muse, mutect2
- KREMEN1 | c.612C>T p.I204= (on ENST00000407188; = p.I206= on NM_032045.5) | Silent (SNP) | VAF 7/41 reads (17%) | called by muse, mutect2
- LZTS2 | c.973C>T p.L325= | Silent (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- TRAPPC9 | c.3273C>T p.L1091= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs753743485; called by muse, mutect2, varscan2
- AC011840.1 | n.957G>A | RNA (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- DGLUCY | c.*68G>T | 3'UTR (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- GALNT10 | c.1056+33C>T | Intron (SNP) | VAF 3/33 reads (9%) | catalogued as rs1480934191; called by muse, mutect2
- GAS2L3 | c.648+42A>T | Intron (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- IQCF5 | c.5-26T>C | Intron (SNP) | VAF 27/50 reads (54%) | catalogued as rs1312386365; called by muse, mutect2, varscan2
